Somatic mutation profile of tumor specimen TCGA-JY-A6FD-01A (aliquot TCGA-JY-A6FD-01A-11D-A33E-09) from TCGA case TCGA-JY-A6FD, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 51.5 years (18,808 days).
Specimen TCGA-JY-A6FD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0feec5d5-dcee-4a0d-95ef-cdf5e1083c73.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6FD-10A (Blood Derived Normal), aliquot TCGA-JY-A6FD-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/574ce03a-5ebc-4c2a-8d6a-98490c76bf7b

The open-access MAF lists 152 somatic variants for this specimen: 111 protein-altering or splice-affecting, 39 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 39, Nonsense Mutation 11, Frame Shift Del 6, Splice Site 2, Intron 2, In Frame Ins 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.14194C>T p.Q4732* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as rs1555186520; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC098582.1 | c.3014C>T p.P1005L | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52022117; called by muse, mutect2
- ADGRG4 | c.4127dup p.L1376Ffs*4 | Frame Shift Ins (INS) | VAF 12/51 reads (24%) | catalogued as rs748603011; called by mutect2, pindel, varscan2
- CDK5RAP2 | c.4174C>G p.Q1392E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV62576377; called by muse, mutect2, varscan2
- CHCHD2 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.212); catalogued as rs778377000, COSV68169837; called by muse, mutect2, varscan2
- CNKSR3 | c.1471C>T p.R491W | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1185036500; called by muse, mutect2, varscan2
- COL12A1 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs1013873051, COSV59393271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.7176G>C p.W2392C (on ENST00000312481; = p.W2388C on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55201261; called by muse, mutect2, varscan2
- COL6A5 | c.7411C>T p.R2471* (on ENST00000312481; = p.R2467* on NM_153264.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs753445274, COSV55209184; called by muse, mutect2, varscan2
- CPA3 | c.1021C>G p.R341G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.338); catalogued as COSV99936546; called by muse, mutect2, varscan2
- DHX57 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1484481718, COSV54888029; called by muse, mutect2, varscan2
- DYNC2H1 | c.6606G>A p.M2202I | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62086432; called by muse, mutect2, varscan2
- ENGASE | c.2018C>G p.S673C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.436); catalogued as COSV56133737; called by muse, mutect2, varscan2
- GBP1 | c.1641G>C p.E547D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV65083123; called by muse, mutect2, varscan2
- HSD17B13 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1463383779, COSV56345865, COSV56347271; called by muse, mutect2, varscan2
- KCTD3 | c.2157G>C p.L719F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.013); catalogued as COSV52069441; called by muse, mutect2, varscan2
- MEGF6 | c.823C>T p.Q275* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as rs1056269613; called by muse, mutect2, varscan2
- MID2 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.679); catalogued as COSV53313624; called by muse, mutect2, varscan2
- NPC1L1 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs756628304, COSV56923389; called by muse, mutect2, varscan2
- OIT3 | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780471456; called by muse, mutect2, varscan2
- PACRG | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs776149854; called by muse, mutect2, varscan2
- PCDHB7 | c.2168G>T p.C723F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV50827689; called by muse, mutect2, varscan2
- PLBD2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55106030; called by muse, mutect2, varscan2
- PLCH1 | c.1012G>C p.E338Q (on ENST00000340059 / NM_001130960.2; = p.E350Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.646); catalogued as COSV100397901; called by muse, mutect2, varscan2
- RELT | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs750370305, COSV99292622; called by muse, mutect2, varscan2
- SH2D3A | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs866653960; called by muse, mutect2, varscan2
- SLC19A1 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs751719682; called by muse, mutect2, varscan2
- SLC37A1 | c.348C>A p.L116= | Splice Region (SNP) | VAF 7/56 reads (13%) | catalogued as rs199619177, COSV61402142; called by muse, mutect2, varscan2
- SLC6A13 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358037747, COSV100570070; called by muse, mutect2
- SLIT2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as rs1277021289, COSV56561268, COSV99884293; called by muse, mutect2, varscan2
- SLIT2 | c.4376G>C p.R1459T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1322158842; called by muse, mutect2
- SPAG17 | c.4074_4075del p.H1360Qfs*9 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs748378452; called by mutect2, pindel, varscan2
- SPIN4 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.582); catalogued as COSV100633422; called by muse, mutect2, varscan2
- STYXL2 | c.2455A>G p.T819A | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1479827087; called by muse, mutect2, varscan2
- TP53 | c.491del p.K164Sfs*6 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as COSV53097521, COSV53135267, COSV53742507; called by mutect2, pindel, varscan2
- TTN | c.63238G>A p.E21080K (on ENST00000591111; = p.E13656K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen probably damaging (0.994); catalogued as rs374492812; ClinVar: uncertain significance / benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- TTN | c.3295G>A p.V1099M (on ENST00000591111; = p.V1053M on NM_003319.4) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | PolyPhen possibly damaging (0.515); catalogued as rs368282893; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic / likely benign; called by muse, mutect2, varscan2
- WNT8B | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295684275, COSV59324837; called by muse, varscan2
- ADAM10 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- ADGRG4 | c.4490T>C p.M1497T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANAPC1 | c.5639C>G p.S1880* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ARAP2 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- ATP8A1 | c.242T>C p.F81S | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN1A1 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.303); called by muse, mutect2
- C2CD3 | c.5642C>G p.S1881C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- CASK | c.603C>A p.D201E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD1C | c.530T>A p.V177E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CDH11 | c.655A>T p.T219S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CHD9 | c.1779A>C p.K593N | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- CNDP2 | c.1267A>G p.T423A | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CNTN6 | c.1037A>T p.N346I | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COL19A1 | c.3275G>T p.G1092V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBRF | c.1733T>C p.V578A | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- DACT1 | c.1299del p.L435Cfs*72 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, varscan2
- DACT1 | c.1303del p.L435Cfs*72 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2*, pindel, varscan2*
- DHODH | c.574del p.E192Rfs*19 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- DMBT1 | c.6920C>T p.S2307L (on ENST00000338354 / NM_001377530.1; = p.S1550L on NM_004406.3) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNMBP | c.2720+1G>C p.X907_splice | Splice Site (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- DYNC1I2 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO15 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FCHO2 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- FSHR | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRA1 | c.774C>A p.Y258* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- GIPC1 | c.887A>T p.N296I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- GTF3C2 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- HES1 | c.254T>C p.V85A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HMGXB4 | c.249C>G p.Y83* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- ITGAV | c.554G>A p.C185Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNMA1 | c.1999G>T p.A667S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- KMT2D | c.14193G>T p.E4731D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- KMT5B | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LAMC3 | c.3335G>T p.C1112F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- MED12 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MIPEP | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MYB | c.1461+2T>C p.X487_splice | Splice Site (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2, varscan2
- MYO5A | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- NCOA2 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECTIN1 | c.888G>C p.Q296H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- NLGN3 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- NPLOC4 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- OR52I2 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OVGP1 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PARP16 | c.747C>G p.D249E | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDH19 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCSK7 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- PNLIPRP1 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRMT5 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.406); called by muse, varscan2
- RGMA | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE2 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- RPL32 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RPUSD2 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- SMOC2 | c.1201G>A p.D401N (on ENST00000356284 / NM_001166412.2; = p.D412N on NM_022138.3) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SSTR5 | c.273_274insTTG p.L91dup | In Frame Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- SYNE1 | c.6274C>A p.Q2092K (on ENST00000367255 / NM_182961.4; = p.Q2099K on NM_033071.3) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2
- TAS2R30 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, varscan2
- TBC1D32 | c.25C>A p.Q9K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TINAG | c.869A>G p.D290G | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TLE2 | c.1408C>G p.Q470E | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- TLN2 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM145 | c.888C>G p.I296M | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2
- TMEM45A | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTLL7 | c.1745A>T p.N582I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- TUT4 | c.4382A>T p.Q1461L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- VAX2 | c.626del p.G209Afs*11 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- WDR45 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- XPO1 | c.1778A>T p.Q593L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XRN1 | c.4979C>A p.A1660D | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF33A | c.1208A>T p.Q403L (on ENST00000458705 / NM_006974.3; = p.Q404L on NM_006954.2) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF831 | c.1854G>C p.E618D | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ZSCAN5B | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); called by muse, mutect2
- AFG3L2 | c.1245G>A p.K415= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs777760292, COSV52312602; called by muse, mutect2, varscan2
- CALB1 | c.408G>A p.K136= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs903686362; called by muse, mutect2, varscan2
- CAPN12 | c.2064C>T p.T688= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1418021451; called by muse, mutect2
- CARMIL2 | c.1458C>T p.L486= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs771671329; called by muse, mutect2, varscan2
- CCDC178 | c.1824T>G p.L608= | Silent (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- CDH10 | c.1422T>G p.A474= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- CNTRL | c.2620C>T p.L874= | Silent (SNP) | VAF 9/53 reads (17%) | called by muse, mutect2, varscan2
- COL17A1 | c.495C>G p.L165= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV62226616; called by muse, mutect2, varscan2
- CYP7B1 | c.234T>A p.G78= | Silent (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- DNAI2 | c.1152C>T p.G384= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs762652711, COSV56759184; called by muse, mutect2, varscan2
- DST | c.4923A>T p.T1641= | Silent (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- EFNA5 | c.318C>T p.H106= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs779367666; called by muse, mutect2, varscan2
- FAP | c.1395C>G p.V465= | Silent (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- FOXJ2 | c.1323C>T p.F441= | Silent (SNP) | VAF 8/35 reads (23%) | called by muse, mutect2, varscan2
- HCFC1 | c.4041T>C p.G1347= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- IGHV4-59 | c.93G>A p.V31= | Silent (SNP) | VAF 32/200 reads (16%) | catalogued as rs781835532; called by muse, mutect2, varscan2
- IQSEC2 | c.3078C>G p.P1026= (on ENST00000642864 / NM_001111125.3; = p.P821= on NM_015075.2) | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- JADE3 | c.1878G>A p.P626= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs781805711; called by muse, mutect2, varscan2
- KCNH2 | c.3366G>A p.P1122= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs371473271, COSV51235326; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- LILRA2 | c.375C>A p.L125= | Silent (SNP) | VAF 45/277 reads (16%) | called by muse, mutect2, varscan2
- MARCHF6 | c.306A>G p.A102= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- MFNG | c.435C>T p.N145= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- NAGS | c.1290G>C p.L430= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs1411823216; called by muse, mutect2, varscan2
- NRCAM | c.3852G>A p.P1284= (on ENST00000379028 / NM_001371124.1; = p.P1163= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs375886714; called by muse, mutect2, varscan2
- OBSCN | c.7584C>T p.L2528= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1390919408; called by muse, mutect2, varscan2
- PGD | c.174G>A p.L58= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- PLPPR3 | c.52C>T p.L18= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- PPM1D | c.507C>T p.S169= | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- PTPRS | c.1224C>T p.I408= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs2230609; called by muse, mutect2, varscan2
- REN | c.225C>T p.S75= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs374481579; called by muse, mutect2, varscan2
- RPP25 | c.549G>C p.A183= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1485108833; called by muse, mutect2, varscan2
- SCN9A | c.2853C>T p.V951= (on ENST00000303354; = p.V940= on NM_002977.3) | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs764006250, COSV57622617; ClinVar: likely benign; called by muse, mutect2, varscan2
- SFTPA2 | c.30C>T p.L10= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- SLC41A1 | c.39G>A p.L13= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV65650991; called by muse, mutect2, varscan2
- SUN1 | c.2205G>A p.K735= (on ENST00000405266 / NM_001367651.1; = p.K615= on NM_025154.6 and 13 other RefSeq transcripts) | Silent (SNP) | VAF 6/32 reads (19%) | called by muse, mutect2, varscan2
- SYT7 | c.1188C>A p.A396= | Silent (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- TCERG1 | c.249A>G p.G83= | Silent (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- UMOD | c.1263C>A p.I421= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- ZDHHC15 | c.657G>T p.V219= | Silent (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- NECTIN1 | c.1003+566G>A | Intron (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- PDXK | c.88-1429C>T | Intron (SNP) | VAF 6/53 reads (11%) | called by muse, mutect2, varscan2
